Gene-level copy-number profile of tumor specimen ALCH-AEEK-TTP1-A from ALCHEMIST case ALCH-AEEK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,464 days).
Specimen ALCH-AEEK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de45059b-bb57-40f0-983b-a37f868f7abf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEEK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/2b656633-45a8-4336-8c31-c4d45f339a9a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 197; copy number 1: 26,876; copy number 2: 30,653; copy number 3: 946; copy number 4: 154; copy number 5: 60; copy number 7: 4; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 180 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,434,843–219,493,629, 1 gene (within-gene range 0–2): SPEG.
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr3:177,503,303–177,503,552, 1 gene (within-gene range 0–1): RN7SKP52.
- chr4:1,574,062–1,580,253, 1 gene: AC147067.1.
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:659,862–693,352, 2 genes (within-gene range 0–1): TPPP, AC026740.1.
- chr5:1,050,384–1,112,063, 2 genes (within-gene range 0–2): SLC12A7, MIR4635.
- chr5:180,601,506–180,649,624, 1 gene: FLT4.
- chr7:155,799,980–155,812,463, 1 gene: SHH.
- chr8:64,091–2,006,936, 41 genes: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:143,945,191–143,945,279, 1 gene (within-gene range 0–1): MIR661.
- chr9:27,829,276–27,944,497, 2 genes: AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene (within-gene range 0–1): AL451124.1.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr9:121,444,991–121,520,424, 3 genes (within-gene range 0–1): GGTA1, RN7SL187P, HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–1): AL357936.1.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–1): NEK6, AL162724.2, AL162724.1.
- chr9:136,494,433–136,546,048, 3 genes (within-gene range 0–1): NOTCH1, MIR4673, AL592301.1.
- chr11:298,200–299,526, 1 gene: IFITM5.
- chr13:112,894,378–114,132,623, 42 genes: MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1.
- chr14:104,579,764–104,590,515, 2 genes (within-gene range 0–2): C14orf180, BX927359.1.
- chr15:52,800,168–52,805,972, 1 gene: AC016044.1.
- chr15:90,883,695–90,895,776, 1 gene: FES.
- chr16:2,088,708–2,136,129, 10 genes (within-gene range 0–1): PKD1, MIR1225, AC009065.2, AC009065.5, MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516, MIR3180-5.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–2): AC137932.3.
- chr17:19,719,059–19,748,943, 3 genes: AC005722.3, AC005722.4, ALDH3A1.
- chr17:50,543,058–50,562,108, 2 genes (within-gene range 0–2): SPATA20, CACNA1G-AS1.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:18,899,514–18,919,387, 1 gene (within-gene range 0–1): COPE.
- chr19:20,399,272–20,571,095, 4 genes (within-gene range 0–1): MIR1270, BNIP3P22, AC008554.1, BNIP3P23.
- chr21:46,098,112–46,155,579, 3 genes: COL6A2, FTCD, FTCD-AS1.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–1): RSPH14, GNAZ, Metazoa_SRP, U7.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–1): CABP7.
- chr22:45,000,565–45,003,619, 1 gene (within-gene range 0–1): AL079301.1.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–1): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:101,387,299–103,501,895, 58 genes, copy number 5 (within-gene range 2–5): LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr16:28,749,959–28,772,807, 2 genes, copy number 7: AC145285.5, NPIPB9.
- chr21:43,092,956–43,162,277, 3 genes, copy number 5–8: U2AF1, MRPL51P2, AP001631.1.
- chr21:44,172,169–44,194,338, 2 genes, copy number 7: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 24,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
